FM case AD1405 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/2c6cf706-7026-484f-9bc5-8edb751178ad

Female, 47.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the fallopian tube; metastasis biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
